Gene-level copy-number profile of tumor specimen TCGA-C4-A0F6-01A from TCGA case TCGA-C4-A0F6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.0 years (29,951 days).
Specimen TCGA-C4-A0F6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.98bf8cd9-4d14-46d2-b20a-d2c7533e4391.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C4-A0F6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e0fe62c-68ba-4407-bcc9-81c4f1e5ffad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 168; copy number 2: 8,334; copy number 3: 25,829; copy number 4: 12,994; copy number 5: 2,544; copy number 6: 7,006; copy number 7: 2,749; copy number 10: 85; copy number 45: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C4-A0F6-01A-11D-A10T-01): tumor purity 0.68, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,956,444, 30 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3.
- chr10:87,642,607–87,747,705, 2 genes (within-gene range 0–2): RPS26P38, PAPSS2.
- chr10:88,259,129–89,207,317, 25 genes: AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H.
- chr10:130,962,588–131,311,721, 3 genes (within-gene range 0–2): MIR378C, TCERG1L, TCERG1L-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,185 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,575,858–69,959,097, 41 genes, copy number 45: Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 45: AC078922.1.
- chr14:21,887,857–22,509,406, 85 genes, copy number 10 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 7 (broad region; genes not listed).
- chr22:22,547,701–38,656,629, 604 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
